Somatic mutation profile of tumor specimen TCGA-ZB-A96L-01A (aliquot TCGA-ZB-A96L-01A-11D-A428-09) from TCGA case TCGA-ZB-A96L, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B3, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 70.9 years (25,914 days).
Specimen TCGA-ZB-A96L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37d1e6a5-546c-4923-b6f2-2f0bacf60cba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A96L-10A (Blood Derived Normal), aliquot TCGA-ZB-A96L-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64a066b6-526a-407a-9b59-ffed37ed2aa6

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 146/426 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- ARMC5 | c.755C>G p.A252G | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.051); catalogued as rs1017934149, COSV51655665; called by mutect2, varscan2
- CATSPER1 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751535876; called by muse, mutect2, varscan2
- FGD4 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.143); catalogued as COSV56786178; called by muse, mutect2, varscan2
- LRRC1 | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as rs199592597; called by muse, mutect2, varscan2
- PREX1 | c.3530G>A p.R1177Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1359762426, COSV100906622; called by muse, mutect2
- SLC27A3 | c.1493C>T p.T498M (on ENST00000271857; = p.T370M on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs151230291; called by muse, mutect2, varscan2
- TTN | c.32101C>T p.R10701W (on ENST00000591111; = p.R9774W on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | PolyPhen benign (0); catalogued as rs372118864; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TXLNA | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV65315213; called by muse, mutect2
- HCAR2 | c.588G>C p.E196D | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- IGSF9B | c.2210C>G p.A737G | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- LIPC | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- MRPL47 | c.355_397del p.A119Ifs*3 | Frame Shift Del (DEL) | VAF 35/79 reads (44%) | called by mutect2, pindel, varscan2
- NEDD4 | c.3068A>G p.Y1023C (on ENST00000508342 / NM_001284338.1; = p.Y604C on NM_006154.4) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPM3 | c.696A>C p.K232N | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CCDC148 | c.18T>G p.A6= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV51766964; called by muse, mutect2, varscan2
- DPPA2 | c.102C>T p.D34= | Silent (SNP) | VAF 44/92 reads (48%) | catalogued as rs572153453, COSV72117901; called by muse, mutect2, varscan2
- KLHDC4 | c.1284G>A p.G428= | Silent (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- SLC9C1 | c.1641A>G p.A547= | Silent (SNP) | VAF 45/73 reads (62%) | catalogued as rs199866303; called by muse, mutect2, varscan2
- NACA | c.71-4197del | Intron (DEL) | VAF 4/28 reads (14%) | called by pindel, varscan2
